Somatic mutation profile of tumor specimen MP2PRT-PAUIWF-TMP1-A (aliquot MP2PRT-PAUIWF-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUIWF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,552 days).
Specimen MP2PRT-PAUIWF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d317c6d0-2f14-4e05-be2b-baae50866410.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUIWF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUIWF-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8b31709-2346-435a-81de-8e9e30f478e9

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6, In Frame Ins 2, Frame Shift Ins 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.4375C>T p.R1459* | Nonsense Mutation (SNP) | VAF 112/300 reads (37%) | catalogued as rs398123953, CM950342, COSV63738314; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP12A | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 101/269 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs769843394, COSV54517514, COSV54518970; called by muse, mutect2, varscan2
- CYP11B2 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 116/344 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs754048592; called by muse, mutect2, varscan2
- DHRS7C | c.796G>A p.V266M (on ENST00000330255 / NM_001220493.2; = p.V265M on NM_001105571.3) | Missense Mutation (SNP) | VAF 212/549 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs774255168, COSV57651134; called by muse, mutect2, varscan2
- FAM71E2 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 261/602 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs553884109; called by muse, mutect2, varscan2
- LRP1 | c.5348G>A p.R1783Q | Missense Mutation (SNP) | VAF 165/481 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs766276294, COSV54528507; called by muse, mutect2, varscan2
- MN1 | c.2942C>T p.A981V | Missense Mutation (SNP) | VAF 331/854 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100179593; called by muse, mutect2, varscan2
- OR14J1 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 113/308 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147619517; called by muse, mutect2, varscan2
- SEC14L5 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778316449, COSV52039575; called by muse, mutect2
- TRAF3IP3 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 104/299 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs564537532, COSV99161618; called by muse, mutect2, varscan2
- USH1G | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 203/580 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs1010293771; called by muse, mutect2, varscan2
- ARMCX5 | c.1414G>T p.A472S | Missense Mutation (SNP) | VAF 43/323 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- ASB14 | c.1568A>C p.E523A | Missense Mutation (SNP) | VAF 82/216 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- BEND2 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 118/626 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by mutect2, varscan2
- DLX5 | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 133/400 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNA11 | c.133dup p.L45Pfs*121 | Frame Shift Ins (INS) | VAF 210/625 reads (34%) | called by mutect2, pindel, varscan2
- IGKV1OR2-108 | chr2:113406870 ins TTAGGGACTTT | In Frame Ins (INS) | VAF 60/197 reads (30%) | called by mutect2, pindel, varscan2
- IL7R | c.715_716insGGCTTCCGTGCCTGG p.M238_D239insGLPCL | In Frame Ins (INS) | VAF 45/234 reads (19%) | called by mutect2, pindel, varscan2
- KMT2D | c.2850_2851dup p.L951Pfs*8 | Frame Shift Ins (INS) | VAF 161/517 reads (31%) | called by mutect2, pindel, varscan2
- PAQR8 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 119/306 reads (39%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- TRIM33 | c.1285_1288del p.L429Tfs*5 | Frame Shift Del (DEL) | VAF 159/407 reads (39%) | called by mutect2, pindel*
- CABIN1 | c.3780C>T p.A1260= | Silent (SNP) | VAF 126/349 reads (36%) | called by muse, mutect2, varscan2
- ERMP1 | c.690C>T p.R230= | Silent (SNP) | VAF 101/407 reads (25%) | catalogued as rs754836111, COSV53037825; called by muse, mutect2, varscan2
- MED28 | c.15A>T p.L5= | Silent (SNP) | VAF 202/624 reads (32%) | catalogued as rs1270351193; called by muse, mutect2, varscan2
- SDHAF3 | c.33A>C p.A11= | Silent (SNP) | VAF 119/332 reads (36%) | called by muse, mutect2, varscan2
- THSD4 | c.1431C>T p.G477= | Silent (SNP) | VAF 178/465 reads (38%) | catalogued as rs762593257, COSV55961031; called by muse, mutect2, varscan2
- TPO | c.252C>T p.S84= | Silent (SNP) | VAF 241/619 reads (39%) | catalogued as rs771322429; called by muse, mutect2, varscan2
